Somatic mutation profile of tumor specimen 0DR0CT from CCDI case PBCFDU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.8 years (2,836 days).
Specimen 0DR0CT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa8707ca-b131-47f0-be38-062ededfe4bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR0CC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee588dff-3c94-4da1-aefd-7029ebe0b6a8

The open-access MAF lists 52 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 8, Intron 3, 5'UTR 3, 3'UTR 3, Splice Region 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 349/989 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 528/665 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKMY1 | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 166/1091 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1265727504; called by muse, mutect2, varscan2
- BRD4 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 52/644 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV54587317; called by muse, mutect2
- DIPK2A | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 54/706 reads (8%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.984); catalogued as rs201605316, COSV59857819; called by muse, mutect2
- DOCK5 | c.3362G>A p.R1121Q | Missense Mutation (SNP) | VAF 70/1174 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs753133870; called by muse, mutect2
- ELN | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 249/940 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1013508230; called by muse, mutect2, varscan2
- MAP1LC3C | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 38/1190 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61804122; called by muse, mutect2
- OR14C36 | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 124/1148 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV58602870; called by mutect2, varscan2
- SH3TC1 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs756506881; called by muse, mutect2, varscan2
- TAB3 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 38/1328 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs929502747; called by muse, mutect2
- TNN | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 99/712 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs764289435; called by muse, mutect2, varscan2
- TTC6 | c.1340C>A p.P447H (on ENST00000267368; = p.P1813H on NM_001310135.3) | Missense Mutation (SNP) | VAF 111/604 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57451821; called by mutect2, varscan2
- ATF7 | c.1055G>A p.R352H (on ENST00000548446 / NM_001366555.2; = p.R341H on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 135/357 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIRC3 | c.856A>T p.N286Y | Missense Mutation (SNP) | VAF 31/864 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2
- BTN3A3 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 85/788 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP135 | c.2142G>C p.K714N | Missense Mutation (SNP) | VAF 62/1897 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2
- DNAI3 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 167/1367 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- EIF5 | c.1023C>G p.Y341* | Nonsense Mutation (SNP) | VAF 600/1119 reads (54%) | called by muse, mutect2, varscan2
- EIF5B | c.2062-2A>T p.X688_splice | Splice Site (SNP) | VAF 86/732 reads (12%) | called by muse, mutect2, varscan2
- EPHB1 | c.1780T>A p.Y594N | Missense Mutation (SNP) | VAF 512/1519 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- JCAD | c.2383C>A p.P795T | Missense Mutation (SNP) | VAF 26/922 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2
- NF1 | c.5920_5924dup p.D1976Ffs*5 (on ENST00000358273 / NM_001042492.3; = p.D1955Ffs*5 on NM_000267.3) | Frame Shift Ins (INS) | VAF 552/764 reads (72%) | called by mutect2, varscan2
- OR6B1 | c.243A>T p.L81F | Missense Mutation (SNP) | VAF 131/1012 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- PCARE | c.3666C>A p.N1222K | Missense Mutation (SNP) | VAF 51/863 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- PIK3C3 | c.740del p.L247* | Frame Shift Del (DEL) | VAF 64/486 reads (13%) | called by pindel, varscan2
- PYHIN1 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 189/1320 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- RFX1 | c.2002G>A p.V668M | Missense Mutation (SNP) | VAF 41/418 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- SFMBT2 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 235/1334 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- THSD4 | c.1120G>T p.G374C | Missense Mutation (SNP) | VAF 104/582 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRNAU1AP | c.225+7A>C | Splice Region (SNP) | VAF 51/513 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.63547G>C p.A21183P (on ENST00000591111; = p.A13759P on NM_003319.4) | Missense Mutation (SNP) | VAF 153/1333 reads (11%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP8 | c.3145A>G p.K1049E | Missense Mutation (SNP) | VAF 95/534 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZFYVE26 | c.4386G>T p.W1462C | Missense Mutation (SNP) | VAF 24/511 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); called by muse, mutect2
- ZNF280A | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 102/825 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- BIRC6 | c.429C>T p.I143= | Silent (SNP) | VAF 140/1342 reads (10%) | called by muse, mutect2, varscan2
- DSC1 | c.1311T>A p.I437= | Silent (SNP) | VAF 159/783 reads (20%) | called by muse, mutect2, varscan2
- F5 | c.5121C>T p.T1707= | Silent (SNP) | VAF 166/1490 reads (11%) | called by muse, mutect2, varscan2
- KLHL21 | c.1347G>A p.S449= | Silent (SNP) | VAF 231/703 reads (33%) | catalogued as rs778618409; called by muse, mutect2, varscan2
- MED14 | c.42C>A p.P14= | Silent (SNP) | VAF 41/340 reads (12%) | catalogued as COSV61358257; called by muse, mutect2, varscan2
- PRUNE2 | c.3489G>A p.P1163= | Silent (SNP) | VAF 123/592 reads (21%) | catalogued as rs768914849, COSV65037576; called by muse, mutect2, varscan2
- TRPM4 | c.2391C>T p.F797= | Silent (SNP) | VAF 32/227 reads (14%) | catalogued as rs1431836954; called by muse, mutect2, varscan2
- ZNF35 | c.318T>C p.H106= | Silent (SNP) | VAF 159/812 reads (20%) | called by muse, mutect2, varscan2
- FGG | c.*423del | 3'UTR (DEL) | VAF 56/358 reads (16%) | called by mutect2, pindel, varscan2
- GUCD1 | c.*54del | 3'UTR (DEL) | VAF 46/187 reads (25%) | called by mutect2, pindel, varscan2
- IL19 | c.-83C>A | 5'UTR (SNP) | VAF 153/1508 reads (10%) | called by muse, mutect2, varscan2
- LETM2 | c.*80G>C | 3'UTR (SNP) | VAF 30/478 reads (6%) | called by muse, mutect2
- MPZ | c.645+62A>G | Intron (SNP) | VAF 80/520 reads (15%) | called by muse, mutect2, varscan2
- PCMT1 | c.-8C>G | 5'UTR (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- SUSD4 | c.725-5538G>A | Intron (SNP) | VAF 329/800 reads (41%) | catalogued as rs770496886; called by muse, mutect2, varscan2
- TFAP2A | c.-36C>T | 5'UTR (SNP) | VAF 146/253 reads (58%) | called by muse, mutect2, varscan2
- TTN | c.35375-1048C>T | Intron (SNP) | VAF 118/458 reads (26%) | called by muse, varscan2
